Somatic mutation profile of tumor specimen TCGA-DW-7842-01A (aliquot TCGA-DW-7842-01A-11D-2136-08) from TCGA case TCGA-DW-7842, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 52.5 years (19,166 days).
Specimen TCGA-DW-7842-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba9b0797-4e79-4b69-a2ce-19dcb7bcb21c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DW-7842-10A (Blood Derived Normal), aliquot TCGA-DW-7842-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/595ab9d9-cf93-45df-aded-5fdb12178cff

The open-access MAF lists 25 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 3, RNA 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APCDD1 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs112875590; called by muse, mutect2, varscan2
- ARHGEF17 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV55236296; called by muse, mutect2, varscan2
- C11orf49 | c.280G>T p.D94Y | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs764723559, COSV53569536; called by muse, mutect2, varscan2
- CCDC180 | c.3213A>G p.I1071M | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.84); PolyPhen benign (0.044); catalogued as COSV63833826; called by muse, mutect2, varscan2
- DOCK4 | c.5728C>G p.L1910V | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as COSV70241729; called by muse, mutect2
- DSG4 | c.1361A>T p.K454M | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV57396182; called by muse, mutect2, varscan2
- FOXE3 | c.428A>C p.N143T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV58633111; called by muse, mutect2, varscan2
- GALNT11 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 103/139 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1345522893, COSV57427970; called by muse, mutect2, varscan2
- GNG10 | c.82-1G>A p.X28_splice | Splice Site (SNP) | VAF 13/39 reads (33%) | catalogued as COSV65349926; called by muse, mutect2, varscan2
- MED17 | c.1645C>A p.L549M | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV52602613; called by muse, mutect2, varscan2
- MYOM2 | c.3209C>T p.T1070I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as rs980135880, COSV50753734; called by muse, mutect2, varscan2
- NLRP5 | c.29G>A p.G10E | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.972); catalogued as COSV66763095; called by muse, mutect2, varscan2
- PLA2G4F | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV51828790; called by muse, mutect2, varscan2
- PROM2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV58300086; called by muse, mutect2, varscan2
- PTGDR | c.361C>A p.L121M | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV60094775; called by muse, mutect2, varscan2
- PTGDR | c.362T>G p.L121R | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60094782; called by muse, mutect2, varscan2
- RPAP3 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 43/76 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV50042623; called by muse, mutect2, varscan2
- TICRR | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs868062880, COSV51539807; called by muse, mutect2
- VIM | c.923C>G p.A308G | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV56407208; called by muse, mutect2, varscan2
- WDR18 | c.1025A>G p.H342R | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.441); catalogued as COSV52123106; called by muse, mutect2, varscan2
- ARHGAP21 | c.3442dup p.R1148Pfs*4 | Frame Shift Ins (INS) | VAF 36/96 reads (38%) | called by mutect2, pindel, varscan2
- ATG16L1 | c.411T>C p.T137= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as COSV61467361; called by muse, mutect2, varscan2
- PEA15 | c.69C>A p.L23= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV58785474; called by muse, mutect2, varscan2
- VPS26B | c.975C>T p.T325= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as rs775679618, COSV55546203; called by muse, mutect2, varscan2
- EI24P4 | n.953C>G | RNA (SNP) | VAF 52/484 reads (11%) | called by muse, mutect2, varscan2
